Surgical pathology report (de-identified scan), TCGA case TCGA-HZ-7926, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HZ-7926-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

* Final Report *

Result type:
Result date:
Result status:
Result title:
Performed by:
Verified by:
Encounter info:

*** Final Report ***

Clinical History

Pancreatic neoplasm, patient is participating in the

Specimen

#1 Gallbladder
#2 Pancreaticoduodenectomy

Gross Examination

#1 Labeled gallbladder is a 10.5 x 5.0 x up to 2.5 cm intact gallbladder. The serosa is smooth and dusky purple. The mucosa is discolored dark green and velvety. The lumen is filled with a dark green viscid fluid. There are no gallstones present. The wall is up to 0.5 cm thick. Four representative sections, to include the cystic duct margin, is submitted in one cassette.

#2 Received fresh, placed in formalin for overnight fixation labeled pancreaticoduodenectomy is a specimen consisting of a 7.0 x 4.0 x 3.5 cm portion of distal stomach contiguous with a 16.0 cm long, 4.0 cm in average diameter portion of small bowel with attached mesentery. There is an attached 8.5 x 5.5 x 3.5 cm portion of pancreas. Within the pancreas is a 3.5 x 3.2 x 3.0 cm ill-defined pale tan-yellow mass. The mass grossly comes to within 0.1 cm of the retroperitoneal tissue margin (inked black), 1.0 cm from the pancreatic resection margin (inked blue), and at least 2.0 cm from the common bile duct margin. The mass surrounds the common bile duct, which is narrowed but still probe patent. Proximal to the narrowing the common bile duct is bifurcated and both lumens are dilated to 1.0 cm in greatest dimension, each. The mass grossly appears to extend into the wall of the small bowel. The overlying mucosa, including the ampulla, is raised and granular over 2.5 x 1.7 cm. The mass is 2.0 cm from the ampulla. The mass comes to within 0.1 cm of the outer surface of the pancreas, posteriorly (also inked black). The remaining pancreatic parenchyma is firm, tan-yellow, and lobulated. There are no additional masses identified. The mucosa of the small bowel and stomach is tan and glistening. There are no mucosal-based masses identified. There are multiple peripancreatic lymph node candidates, up to 0.8 cm in greatest dimension. There is a 1.6 cm in greatest dimension lymph node candidate identified adjacent to the bile duct margin. Within the perigastric adipose tissue are multiple additional lymph node candidates, up to 0.4 cm. There is no attached small bowel mesentery. Representative sections submitted in fifteen: "A"- "O". Block summary: the following margin sections are tangential in nature; "A" bifurcated bile duct;

Printed by:
Printed on:

Page 1 of 3
(Continued)

[page 2 of 3]
Surgical Pathology Report

* Final Report *

"B" proximal (stomach); "C" distal (small bowel); "D", "E" pancreatic resection margin; "F", "G" mass with respect to the retroperitoneal margin, perpendicular; "H" cross section through the ampulla to include bile duct, underlying pancreas, and portion of mass; "I" mass with overlying small bowel; "J" - ----- with respect to the outer surface of the pancreas (inked black), perpendicular; "K" additional section of the mass and adjacent bile duct; "L" uninvolved pancreas; "M" multiple individual peripancreatic lymph node candidates; "N" bile duct lymph node candidate, bisected; "O" multiple individual perigastric lymph node candidates. [REDACTED]

OR Consultation

#2 PANCREATIC DUODENECTOMY: TISSUE TRIAGED FOR [REDACTED]

Signature Line

Signed by: [REDACTED]
ELECTRONIC SIGNATURE

Microscopic Examination

#1 Microscopic examination performed.

#2 Sections of the pancreatic mass demonstrate a well differentiated pancreatic ductal adenocarcinoma composed of irregular glandular structures lined by a malignant cell population with nuclear pleomorphism and nucleoli formation. The adenocarcinoma extends into the peripancreatic soft tissue and is less than 0.1 cm away from the retroperitoneal margin. However, some of the retroperitoneal margin sections contain significant cautery artifact which blurs the retroperitoneal margin sections. The bile duct, proximal stomach, distal duodenum and pancreatic margins are all free of adenocarcinoma. The adenocarcinoma extends into the duodenum and extensively involves the duodenum as well as the ampulla. In the ampullary section, there is lymphovascular space invasion beneath the mucosal surface of the ampulla. Extensive perineural invasion is noted. Sections labeled "2M" of the peripancreatic lymph nodes demonstrate metastatic adenocarcinoma in two of four lymph nodes. The remaining lymph node sections, ("2N", "2O") are free of adenocarcinoma. There is metastatic adenocarcinoma in a total of two of thirteen lymph nodes.

COMMENT:

#2 There is marked cautery effect at the retroperitoneal soft tissue surgical margin, which impairs assessment of this margin. Although this margin is technically free of adenocarcinoma, I am suspicious that this margin is involved by adenocarcinoma. [REDACTED]

Final Diagnosis

#1 GALLBLADDER: MILD CHRONIC CHOLECYSTITIS.
#2 PANCREATIC DUODENECTOMY: WELL DIFFERENTIATED ADENOCARCINOMA, PANCREATIC DUCTAL

Printed by:
Printed on: [REDACTED]

Page 2 of 3
(Continued)

[page 3 of 3]
Surgical Pathology Report

* Final Report *

TYPE.

TUMOR LOCATION: HEAD OF PANCREAS.

TUMOR SIZE: 3.5 X 3.2 X 3.0 CM.

MICROSCOPIC TUMOR EXTENSION: ADENOCARCINOMA INVADES RETROPERITONEAL
ADIPOSE TISSUE, DUODENAL WALL, AMPULLA OF VATER.

SURGICAL MARGIN STATUS:

PROXIMAL STOMACH, DISTAL DUODENAL SURGICAL MARGINS FREE OF CARCINOMA.

COMMON BILE DUCT SURGICAL MARGIN FREE OF CARCINOMA.

PANCREATIC SURGICAL MARGIN FREE OF CARCINOMA.

ADENOCARCINOMA EXTENDS TO WITHIN LESS THAN 0.1 CM OF RETROPERITONEAL
MARGIN (SEE COMMENT).

LYMPHOVASCULAR SPACE STATUS: LYMPHOVASCULAR SPACE INVASION

IDENTIFIED.

PERINEURAL STATUS: PERINEURAL INVASION IDENTIFIED.

ADDITIONAL PATHOLOGIC FINDINGS: CHRONIC PANCREATITIS.

LYMPH NODE STATUS: METASTATIC ADENOCARCINOMA INVOLVING TWO OF THIRTEEN
LYMPH NODES (2/13).

EXTRACAPSULAR LYMPH NODE STATUS: NEGATIVE FOR CARCINOMA.

PATHOLOGIC STAGE (TNM CLASSIFICATION): pT3 pN1.

Ordering Provider

Ordering Physician:

Printed by:
Printed on:

Page 3 of 3
(End of Report)

Source: NCI Genomic Data Commons file d3595a8f-9993-4d81-96fc-99f6273c4cc4 (TCGA-HZ-7926.F592ECC6-667A-41FB-B56A-9A860A016130.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).